Somatic mutation profile of tumor specimen 0DLSXU from CCDI case PBBZJN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 13.7 years (5,005 days).
Specimen 0DLSXU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 511f1aa0-516c-44b2-97e1-7a7ec3d4db54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLSX6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/400508a3-2fe6-477f-bfd3-197bbfb91b95

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.2650A>C p.K884Q | Missense Mutation (SNP) | VAF 444/484 reads (92%) | SIFT tolerated (1); PolyPhen probably damaging (0.988); catalogued as CM910047; called by muse, varscan2
- PML | c.2441G>A p.R814H | Missense Mutation (SNP) | VAF 270/582 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs200577511, COSV51448419; called by muse, varscan2
- PUS10 | c.1551G>C p.E517D | Missense Mutation (SNP) | VAF 274/626 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs750333610; called by muse, varscan2
- SPATA31A6 | c.3813C>G p.S1271R | Missense Mutation (SNP) | VAF 134/776 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.115); catalogued as rs754271517; called by muse, varscan2
- COL12A1 | c.5999A>C p.Y2000S | Missense Mutation (SNP) | VAF 492/526 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SPATA31A1 | c.3825C>G p.S1275R | Missense Mutation (SNP) | VAF 214/1238 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.394); called by muse, varscan2
- ZNF263 | c.264G>T p.Q88H | Missense Mutation (SNP) | VAF 323/650 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, varscan2
- ITSN1 | c.360C>T p.I120= | Silent (SNP) | VAF 241/678 reads (36%) | catalogued as rs745493656, COSV66080936; called by muse, varscan2
- NUDT2 | c.288G>A p.A96= | Silent (SNP) | VAF 200/494 reads (40%) | catalogued as rs776295589; called by muse, varscan2
- OR14K1 | c.873G>A p.K291= | Silent (SNP) | VAF 752/1714 reads (44%) | called by muse, varscan2
- SYK | c.1218C>T p.N406= | Silent (SNP) | VAF 710/1575 reads (45%) | catalogued as rs202093746; called by muse, varscan2
- NFE2L2 | c.402+73G>T | Intron (SNP) | VAF 161/374 reads (43%) | called by muse, varscan2
- POTEM | c.918-70T>C | Intron (SNP) | VAF 32/53 reads (60%) | catalogued as rs199892710; called by muse, varscan2
